Surgical pathology report (de-identified scan), TCGA case TCGA-60-2695, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2695-01A (Primary Tumor).

[page 1 of 4]
Institute

SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R RIGHT DISTAL PARATRACHEAL
B. 4L LEFT DISTAL PARATRACHEAL
C. 7 SUBCARINAL
D. LEVEL 5 LYMPH NODE
E. LEFT UPPER LOBE
F. LEVEL 2 LYMPH NODE
G. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Small cell CA of LU lobe

INTRAOPERATIVE CONSULTATION:

FSA/TPA-FSB-FSC-FSD/TPD: No tumor seen. Diagnosis called to [REDACTED]

FSE1: Bronchial margin: Negative. Diagnosis called to [REDACTED]

FSE2: Mass-Poorly differentiated neuroendocrine carcinoma. Diagnosis called to [REDACTED] at [REDACTED]

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL

Received fresh for frozen section are two tan red soft tissue fragments 0.4cm and 0.2cm. A touch prep is taken. Toto FSA.

B. 4L LEFT DISTAL PARATRACHEAL

Received fresh for frozen section are two tan red soft tissue fragments 0.5cm and 0.3cm. Toto FSB.

C. 7 SUBCARINAL

[page 2 of 4]
Received fresh for frozen section are two tan red soft tissue fragments 0.4cm and 0.2cm. Toto FSC.

D. LEVEL 5 LYMPH NODE

Received fresh for frozen section are two tan red soft tissue fragments 0.8 x 0.6 x 0.3cm in aggregate. A touch prep is taken. Toto FSD.

E. LEFT UPPER LOBE

Received fresh for frozen section is a 174g lobectomy specimen 15.0 x 10.0 x 4.0cm. The pleural surface is tan purple and remarkable for a palpable mass. This area is inked black. The bronchial margin is shaved and submitted in FSE1. The specimen is serially sectioned to reveal a 3.3 x 2.5 x 2.4cm well circumscribed gray white mass, abutting the black inked margin and 2.8cm from the bronchial margin. Dissection of the hilum reveals 12 possible lymph nodes ranging from 0.2 x 0.2 x 0.2cm to 0.7 x 0.7 x 0.6cm. The remaining lung parenchyma is grossly unremarkable. A portion of the specimen is submitted for tissue procurement. Representatively submitted:

FSE1: bronchial margin

FSE2: mass

E3: 5 lymph nodes

E4: 4 lymph nodes

E5: 3 lymph nodes

E6-E9: mass with pleural surface

E10-E12: uninvolved parenchyma

F. LEVEL II LYMPH NODE

Received in formalin is a tan brown lymph node 1.2 x 1.0 x 0.8cm. The specimen is bisected. Toto F1.

G. LEVEL 9 LYMPH NODE

Received in formalin is a tan brown lymph node 0.9 x 0.8 x 0.5cm. The specimen is bisected. Toto G1

DIAGNOSIS:

A. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

B. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

C. 7 SUBCARINAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

D. LEVEL 5 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

E. LEFT UPPER LOBE, LOBECTOMY:

- BASALOID SQUAMOUS CELL CARCINOMA, TUMOR SIZE 3.3 X 2.5 CM.

- BRONCHIAL MARGIN, NEGATIVE FOR TUMOR

[page 3 of 4]
- SEVEN PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR TUMOR (0/7)
- SEE IMMUNOSTAIN RESULTS AND TEMPLATE

F. LEVEL 2 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

G. LEVEL 9 LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

SYNOPTIC REPORT - LUNG

Surgical Procedure: Lobectomy
Laterality: Left
Tumor Site: Upper lobe
Tumor Location: Central
Tumor Size: Greatest diameter: 3.3cm
Additional dimensions: 2.5cm x 2.4cm

WHO CLASSIFICATION

Squamous cell carcinoma
Basaloid type 8083/3
Histologic Grade: G3: Poorly differentiated
Angiolymphatic Invasion: Absent
Bronchial Margins: Bronchial margins uninvolved
Visceral Pleural Involvement: Indeterminate
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 7
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 5
N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1
Non-Neoplastic Lung: Emphysematous changes
Additional Pathologic Findings: None identified
Pathological Staging (pTNM): pT 2 N 0 M X

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block E8

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
CD56	Positive	Spotty

[page 4 of 4]
SYNAPTOPHYSIN	Negative
CHROMOGRANIN A	Negative
CYTOKERATIN-HMW-34BE12	Positive
CAM 5.2	Positive
P63	Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the [REDACTED]. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or Immunohistochemical stains were performed with appropriately stained positive and negative controls.

Pathologist
[REDACTED]

Source: NCI Genomic Data Commons file 47c1ce81-50b6-4088-8eee-dc2d87161a24 (TCGA-60-2695.EE5F477A-E6F4-4C37-8EE1-F9DC269AEF9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).